Somatic mutation profile of tumor specimen ALCH-B3B5-TTP1-A (aliquot ALCH-B3B5-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3B5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.2 years (24,181 days).
Specimen ALCH-B3B5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26d78d08-8296-45b4-b549-28688e23ce88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3B5-NB1-A (Blood Derived Normal), aliquot ALCH-B3B5-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e38d984-52a0-4a17-b2d2-694811ac401a

The open-access MAF lists 364 somatic variants for this specimen: 245 protein-altering or splice-affecting, 69 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 200, Silent 69, Intron 26, Nonsense Mutation 17, Frame Shift Del 14, RNA 11, 3'UTR 7, Splice Site 7, In Frame Del 3, 5'Flank 3, 3'Flank 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHCR7 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 122/364 reads (34%) | catalogued as rs1032242817, CM001127; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 143/317 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.446G>A p.R149H (on ENST00000502732 / NM_007314.4; = p.R134H on NM_005158.5) | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as rs148596386; called by muse, mutect2, varscan2
- ADAMTS12 | c.3355C>A p.L1119I | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs139710230; called by muse, mutect2, varscan2
- ADPRHL1 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs199692255, COSV100733512; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1210T>C p.C404R | Missense Mutation (SNP) | VAF 74/500 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.139); catalogued as rs749770850; called by muse, varscan2
- ANKRD30A | c.3180G>T p.R1060S (on ENST00000611781; = p.R1004S on NM_052997.2) | Missense Mutation (SNP) | VAF 100/201 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV64615180; called by muse, mutect2, varscan2
- ASMTL | c.510-1G>C p.X170_splice | Splice Site (SNP) | VAF 7/15 reads (47%) | catalogued as COSV101187645; called by muse, mutect2, varscan2
- BAZ1B | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs1290085350; called by muse, mutect2, varscan2
- CCDC74B | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs138145722; called by muse, mutect2
- CHAT | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 87/165 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.124); catalogued as CM031948; called by muse, mutect2, varscan2
- CHSY3 | c.1515G>T p.M505I | Missense Mutation (SNP) | VAF 114/226 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs537221274; called by muse, mutect2, varscan2
- CLCNKB | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as COSV65160980; called by muse, mutect2, varscan2
- CLTC | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV52245054; called by muse, mutect2, varscan2
- COL12A1 | c.6202G>T p.D2068Y | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV59394737; called by muse, mutect2, varscan2
- CRISP2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 96/364 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100188890; called by muse, mutect2, varscan2
- DACH2 | c.792G>T p.W264C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV64190917; called by muse, mutect2, varscan2
- DEPDC4 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs770385877; called by muse, mutect2, varscan2
- DOP1A | c.2908G>T p.D970Y | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52708460; called by muse, mutect2, varscan2
- DTNA | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.382); catalogued as rs778924121; called by muse, mutect2, varscan2
- EYS | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV104416960; called by muse, mutect2, varscan2
- FAM47C | c.2167G>T p.V723L | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs782084099; called by muse, mutect2, varscan2
- FBXO3 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs769264685; called by muse, mutect2, varscan2
- FLNB | c.5506G>A p.A1836T | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs199964133; called by muse, mutect2, varscan2
- GAB2 | c.1816A>G p.K606E (on ENST00000361507 / NM_080491.3; = p.K568E on NM_012296.3) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1565414714; called by muse, mutect2, varscan2
- GTF2IRD1 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99735739; called by muse, mutect2, varscan2
- HCN1 | c.1520C>A p.A507D | Missense Mutation (SNP) | VAF 116/564 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV57517620; called by muse, mutect2, varscan2
- HS3ST4 | c.984G>T p.W328C | Missense Mutation (SNP) | VAF 121/278 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100500719, COSV58802705; called by muse, mutect2, varscan2
- JAK3 | c.2971A>G p.I991V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.046); catalogued as COSV71685932; called by muse, mutect2
- KRTAP10-6 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 131/447 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV59966602; called by muse, mutect2, varscan2
- LHX8 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 130/391 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV53954620; called by muse, mutect2, varscan2
- LRRC7 | c.863C>T p.S288F (on ENST00000651989 / NM_001370785.2; = p.S255F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs776103608, COSV50451926; called by muse, mutect2, varscan2
- MAGEB18 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57464450; called by muse, mutect2, varscan2
- MAGI3 | c.2822A>G p.H941R | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs765539318; called by muse, mutect2, varscan2
- MAPT | c.775G>A p.A259T (on ENST00000262410 / NM_001377265.1; = p.A184T on NM_016835.4) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as rs377597373, COSV52240437; called by muse, mutect2, varscan2
- MIER2 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 35/150 reads (23%) | catalogued as rs1347911150; called by muse, mutect2, varscan2
- MIOS | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV60769540; called by muse, mutect2, varscan2
- MMRN1 | c.3118G>A p.E1040K | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs746252489; called by muse, mutect2, varscan2
- MRPL34 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs1555721609; called by muse, mutect2, varscan2
- MTUS2 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs756286579; called by muse, mutect2, varscan2
- MYCT1 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 93/337 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.053); catalogued as COSV65891829; called by muse, mutect2, varscan2
- MYO7A | c.3568C>T p.R1190W | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782011801; called by muse, mutect2, varscan2
- NLRP5 | c.3344C>T p.S1115F | Missense Mutation (SNP) | VAF 110/168 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs369505014, COSV101173782; called by muse, mutect2, varscan2
- NUP188 | c.3583G>A p.D1195N | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.532); catalogued as rs761347742; called by muse, varscan2
- OR4A16 | c.8C>G p.P3R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1378267370; called by muse, varscan2
- OR4A16 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as COSV59044815, COSV59045615; called by muse, varscan2
- OR4D5 | c.455del p.G152Afs*6 | Frame Shift Del (DEL) | VAF 44/113 reads (39%) | catalogued as COSV58306683; called by mutect2, pindel, varscan2
- OR52N2 | c.644G>C p.C215S | Missense Mutation (SNP) | VAF 100/356 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs751842037; called by muse, mutect2, varscan2
- OR8H2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs760326744, COSV57945388, COSV57947179; called by muse, mutect2, varscan2
- OVCH1 | c.1568G>T p.G523V | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs780718298; called by muse, mutect2, varscan2
- PEX16 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767624302, COSV53802399; called by muse, mutect2
- PKHD1L1 | c.6311C>A p.A2104E | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs376199434; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1501G>A p.A501T (on ENST00000421990 / NM_001136042.2; = p.A483T on NM_025267.3) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs756426061; called by muse, mutect2, varscan2
- RAB6C | c.316A>T p.K106* | Nonsense Mutation (SNP) | VAF 56/394 reads (14%) | catalogued as COSV101308437; called by muse, mutect2, varscan2
- RASGRF1 | c.1340G>T p.C447F | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69179487; called by muse, mutect2, varscan2
- RB1 | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 109/223 reads (49%) | catalogued as CM030516, COSV57295380; called by muse, varscan2
- RHAG | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100006859; called by muse, mutect2, varscan2
- RIOK2 | c.1138A>G p.S380G | Missense Mutation (SNP) | VAF 101/199 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs191630960; called by muse, mutect2, varscan2
- RTN1 | c.1308C>G p.H436Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.446); catalogued as COSV99954845; called by muse, mutect2
- SEMA3C | c.1892G>T p.R631L | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54853337, COSV54860145; called by muse, mutect2, varscan2
- SEMA6C | c.1437C>A p.C479* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV59003858; called by muse, mutect2, varscan2
- SERPINA7 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100568571; called by muse, mutect2, varscan2
- SMC6 | c.975C>A p.Y325* | Nonsense Mutation (SNP) | VAF 116/294 reads (39%) | catalogued as rs1231229326; called by muse, mutect2, varscan2
- SMCHD1 | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55267825; called by muse, mutect2, varscan2
- SPATA31D1 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as rs372627275; called by muse, mutect2, varscan2
- SPTBN4 | c.6788G>A p.R2263Q | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.377); catalogued as COSV100151707; called by muse, varscan2
- SSPOP | n.13435G>A | Splice Region (SNP) | VAF 30/114 reads (26%) | catalogued as rs1173055955; called by muse, mutect2, varscan2
- STK35 | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs376078164, COSV55690586; called by muse, mutect2, varscan2
- STON2 | c.1564C>T p.Q522* (on ENST00000649389 / NM_001366849.2; = p.Q465* on NM_001256430.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 67/334 reads (20%) | catalogued as rs758479309; called by muse, mutect2, varscan2
- TNPO2 | c.2596G>T p.G866C (on ENST00000425528 / NM_001382240.1; = p.G856C on NM_013433.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1357888812; called by muse, mutect2, varscan2
- TP53 | c.625A>T p.R209* | Nonsense Mutation (SNP) | VAF 117/217 reads (54%) | catalogued as rs1429743956, CM971504, COSV52741360, COSV52840233, COSV53599366; called by muse, mutect2, varscan2
- TPRN | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1377024587, COSV99047958; called by muse, mutect2, varscan2
- TPTE | c.894G>T p.R298S (on ENST00000618007 / NM_199261.4; = p.R280S on NM_199259.4) | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs777956432; called by muse, mutect2, varscan2
- TRHR | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 67/225 reads (30%) | catalogued as rs1332965262, COSV61233315; called by muse, mutect2, varscan2
- UNCX | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.201); catalogued as rs1000447305; called by muse, mutect2, varscan2
- USH2A | c.2530T>A p.C844S | Missense Mutation (SNP) | VAF 107/431 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56379529; called by muse, mutect2, varscan2
- WT1 | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as COSV60071406; called by muse, varscan2
- ZBTB18 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV100700276; called by muse, mutect2, varscan2
- ZNF554 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.983); catalogued as rs374224608; called by muse, mutect2, varscan2
- ABCA4 | c.3556A>T p.T1186S | Missense Mutation (SNP) | VAF 212/641 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA6 | c.2488A>T p.M830L | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCC9 | c.902G>C p.S301T | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- AC242842.3 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 38/805 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACTRT3 | c.14A>T p.Q5L | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ADAM9 | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 127/586 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADAMTS7 | c.3847C>A p.L1283M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ADGRV1 | c.18718T>G p.S6240A | Missense Mutation (SNP) | VAF 79/142 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHCYL1 | c.1576A>T p.N526Y | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- AK9 | c.2617G>C p.V873L | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- AKAP4 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKR1B1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 93/440 reads (21%) | called by muse, mutect2, varscan2
- ANKRD20A1 | c.1210T>C p.C404R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by mutect2, varscan2
- ANKRD30B | c.2559A>T p.Q853H | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- APC2 | c.4370del p.G1457Afs*123 | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- APOL6 | c.402A>T p.K134N | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- ATN1 | c.2821G>T p.D941Y | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- B3GNT7 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.189); called by muse, mutect2
- BCL2L14 | c.416A>T p.Q139L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BEST1 | c.1546C>T p.L516F | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BHMT2 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 98/230 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- BMP5 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 151/555 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CARD11 | c.3028A>T p.T1010S | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CASC3 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CCDC81 | c.1069C>A p.Q357K (on ENST00000445632 / NM_001156474.2; = p.Q267K on NM_021827.4) | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CCDC91 | c.855+2T>A p.X285_splice | Splice Site (SNP) | VAF 38/103 reads (37%) | called by muse, mutect2, varscan2
- CCDC97 | c.829_831del p.E277del | In Frame Del (DEL) | VAF 31/262 reads (12%) | called by pindel, varscan2
- CCNA1 | c.1356T>A p.C452* | Nonsense Mutation (SNP) | VAF 120/255 reads (47%) | called by muse, mutect2, varscan2
- CDK13 | c.3814G>T p.E1272* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- CEP170 | c.923A>T p.K308M | Missense Mutation (SNP) | VAF 121/427 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CEP85L | c.1399del p.S467Afs*10 | Frame Shift Del (DEL) | VAF 55/202 reads (27%) | called by mutect2, pindel, varscan2
- CHST15 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP3P2 | n.1331A>T | Splice Region (SNP) | VAF 26/106 reads (25%) | called by mutect2, varscan2
- COL11A1 | c.1937del p.G646Vfs*26 | Frame Shift Del (DEL) | VAF 108/356 reads (30%) | called by mutect2, pindel, varscan2
- COL1A2 | c.3695T>C p.I1232T | Missense Mutation (SNP) | VAF 104/448 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- COL4A4 | c.4513C>A p.Q1505K | Missense Mutation (SNP) | VAF 105/207 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.1959C>G p.N653K | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- COLEC12 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CRYBG3 | c.3619A>T p.I1207F | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CTCF | c.853A>T p.M285L | Missense Mutation (SNP) | VAF 139/310 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CTNNA3 | c.280G>T p.V94F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTNND2 | c.1481G>A p.G494D | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DCHS1 | c.8978C>A p.P2993Q | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DPRX | c.36_40del p.Q13Afs*11 | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel
- DTNB | c.482T>A p.L161* | Nonsense Mutation (SNP) | VAF 72/182 reads (40%) | called by muse, mutect2, varscan2
- ELFN1 | c.2303A>T p.Y768F | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ELOVL7 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ETFDH | c.1201C>G p.H401D | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.261C>G p.I87M | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- FKBP10 | c.1688C>A p.T563K | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FOXD2 | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- GAS2 | c.128G>T p.W43L | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDF1 | c.471_476del p.A158_P159del | In Frame Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- GOLGA6L6 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- GPC6 | c.648dup p.A217Cfs*67 | Frame Shift Ins (INS) | VAF 50/112 reads (45%) | called by mutect2, pindel, varscan2
- GPC6 | c.1157C>A p.T386K | Missense Mutation (SNP) | VAF 108/211 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HEPH | c.151C>A p.P51T (on ENST00000343002; = p.P105T on NM_138737.5) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP5A | c.71A>T p.D24V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- INSYN2B | c.1364C>G p.T455S | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGAX | c.2623C>A p.Q875K | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ITGB2 | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KAT2A | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA4 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KHDRBS1 | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- KMT2B | c.5425G>T p.A1809S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- KMT2D | c.11446G>T p.G3816* | Nonsense Mutation (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- LILRA2 | c.34+2T>A p.X12_splice | Splice Site (SNP) | VAF 70/202 reads (35%) | called by muse, varscan2
- LRIG3 | c.1071del p.L358Ffs*4 | Frame Shift Del (DEL) | VAF 25/193 reads (13%) | called by mutect2, pindel, varscan2
- LRRC4C | c.1189G>T p.G397W | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRIQ1 | c.3367A>T p.T1123S | Missense Mutation (SNP) | VAF 105/338 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRRK2 | c.3311A>T p.D1104V | Missense Mutation (SNP) | VAF 173/513 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRTM4 | c.938G>T p.W313L | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LSAMP | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MAGEC1 | c.2079A>T p.Q693H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MAN1B1 | c.852G>T p.W284C | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAP2K6 | c.726T>A p.S242R | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MAP3K6 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MEFV | c.133A>T p.I45F | Missense Mutation (SNP) | VAF 195/440 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- MFAP4 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- MORC1 | c.191G>T p.C64F | Missense Mutation (SNP) | VAF 111/422 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MRE11 | c.433A>T p.S145C | Missense Mutation (SNP) | VAF 135/350 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSN | c.972A>T p.E324D | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC19 | c.712G>T p.G238* | Nonsense Mutation (SNP) | VAF 77/271 reads (28%) | called by muse, mutect2, varscan2
- MYO5B | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 121/514 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NR2C2 | c.1111-2A>T p.X371_splice (on ENST00000393102; = p.X390_splice on NM_003298.5) | Splice Site (SNP) | VAF 53/103 reads (51%) | called by muse, mutect2, varscan2
- NR2F2 | c.7A>T p.M3L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUMBL | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 95/280 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- NYAP2 | c.236T>A p.V79E | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- OCSTAMP | c.1345C>A p.L449I | Missense Mutation (SNP) | VAF 103/316 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ODF2L | c.1706C>T p.S569F (on ENST00000317336; = p.S553F on NM_020729.3) | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR11H6 | c.652T>A p.Y218N | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR2B11 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 93/339 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- OR4K1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- OR52N4 | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR8G5 | c.43G>T p.V15F | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ORC1 | c.1868A>G p.D623G | Missense Mutation (SNP) | VAF 52/493 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOG | c.2693C>G p.T898R | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PCDH17 | c.3367C>A p.H1123N | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PCNX2 | c.1744_1745del p.L582Vfs*5 | Frame Shift Del (DEL) | VAF 84/313 reads (27%) | called by mutect2, pindel, varscan2
- PCYT2 | c.643del p.V215Sfs*52 | Frame Shift Del (DEL) | VAF 30/130 reads (23%) | called by mutect2, pindel, varscan2
- PDIA6 | c.141A>G p.I47M | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- PHF12 | c.758dup p.N253Kfs*3 | Frame Shift Ins (INS) | VAF 42/306 reads (14%) | called by mutect2, pindel, varscan2
- PIK3R4 | c.1685C>T p.T562I | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PITPNB | c.769A>T p.M257L | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.10611C>A p.N3537K | Missense Mutation (SNP) | VAF 159/542 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLAC9 | c.163-1G>C p.X55_splice | Splice Site (SNP) | VAF 84/154 reads (55%) | called by muse, mutect2, varscan2
- PLAG1 | c.1204A>G p.K402E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- PLCE1 | c.6741G>C p.K2247N | Missense Mutation (SNP) | VAF 150/313 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PLP1 | c.527T>A p.I176N | Missense Mutation (SNP) | VAF 130/217 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PNLIPRP1 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT tolerated (0.91); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POLR3B | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POTEM | c.1049A>T p.H350L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- PRAMEF10 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 138/498 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PRDM15 | c.1881G>T p.K627N | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRKCG | c.2071C>A p.P691T | Missense Mutation (SNP) | VAF 79/137 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRRT4 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- PTPRB | c.5254G>T p.D1752Y | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASAL2 | c.2547_2560del p.V850Hfs*10 | Frame Shift Del (DEL) | VAF 53/320 reads (17%) | called by mutect2, pindel, varscan2
- RFX3 | c.1751A>G p.Y584C | Missense Mutation (SNP) | VAF 172/355 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- RUSF1 | c.273del p.L91Ffs*20 | Frame Shift Del (DEL) | VAF 28/247 reads (11%) | called by mutect2, pindel, varscan2
- RYK | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RYR2 | c.5713C>A p.Q1905K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- S100P | c.166A>T p.K56* | Nonsense Mutation (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- SEC61A2 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 166/324 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SEMA5A | c.1300del p.V434Yfs*3 | Frame Shift Del (DEL) | VAF 79/226 reads (35%) | called by mutect2, pindel, varscan2
- SETBP1 | c.3255C>A p.F1085L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- SETX | c.5582T>G p.I1861S | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SH3GL3 | c.362T>A p.M121K | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- SHANK2 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, varscan2
- SIX4 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, varscan2
- SLC2A10 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 186/537 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SLC7A11 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SLC8A1 | c.1005G>C p.Q335H | Missense Mutation (SNP) | VAF 68/384 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLITRK3 | c.2724del p.K909Nfs*2 | Frame Shift Del (DEL) | VAF 30/109 reads (28%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1842G>C p.M614I | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SNCAIP | c.1475A>T p.K492M | Missense Mutation (SNP) | VAF 125/260 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SORCS1 | c.969G>T p.M323I | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SPATA31A3 | c.2121G>T p.K707N | Missense Mutation (SNP) | VAF 29/300 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SPINT4 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ST8SIA3 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 95/375 reads (25%) | PolyPhen benign (0.38); called by muse, mutect2, varscan2
- ST8SIA5 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 76/192 reads (40%) | PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- STARD9 | c.9809C>G p.P3270R | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.042); called by muse, mutect2
- STARD9 | c.9811G>A p.A3271T | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2
- STPG2 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT1 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBCEL | c.839+1G>T p.X280_splice | Splice Site (SNP) | VAF 38/243 reads (16%) | called by muse, mutect2, varscan2
- TBX20 | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 88/409 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- THOP1 | c.12del p.A5Qfs*17 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- TMEM132C | c.1219T>G p.Y407D | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMPRSS11B | c.947-2A>G p.X316_splice | Splice Site (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
- TNR | c.3670T>A p.Y1224N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TNXB | c.727_734del p.D243Pfs*15 | Frame Shift Del (DEL) | VAF 62/204 reads (30%) | called by mutect2, pindel, varscan2
- TRAV8-7 | c.211G>C p.A71P | Missense Mutation (SNP) | VAF 125/288 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM2 | c.19A>T p.N7Y (on ENST00000437508; = p.N34Y on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TRIO | c.2974G>T p.V992L | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRPA1 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 153/503 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TULP1 | c.1530_1544del p.E511_T515del | In Frame Del (DEL) | VAF 58/263 reads (22%) | called by mutect2, pindel, varscan2
- VEZT | c.2321A>C p.N774T | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2
- VPS51 | c.102C>G p.H34Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- VSIG4 | c.269A>T p.H90L | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- VWA3A | c.1061T>A p.V354E | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ZNF407 | c.1968G>T p.L656F | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ZNF500 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ZNF69 | c.808C>G p.H270D | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF730 | c.1465T>A p.F489I | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZSCAN16 | c.30A>T p.Q10H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2
- ABHD11 | c.402C>G p.P134= | Silent (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- ADAMTS16 | c.1491T>G p.P497= | Silent (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- ADGRB3 | c.123G>T p.S41= | Silent (SNP) | VAF 93/326 reads (29%) | catalogued as rs771599054, COSV65382111; called by muse, mutect2, varscan2
- ALKBH1 | c.1119G>A p.L373= | Silent (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2
- ALKBH2 | c.543G>A p.G181= | Silent (SNP) | VAF 73/162 reads (45%) | called by muse, mutect2, varscan2
- ANAPC1 | c.5670C>G p.V1890= | Silent (SNP) | VAF 38/265 reads (14%) | called by muse, mutect2, varscan2
- APC2 | c.2622C>G p.L874= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99279250; called by muse, mutect2, varscan2
- APLNR | c.957C>A p.A319= | Silent (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2, varscan2
- ARNT | c.252G>C p.A84= | Silent (SNP) | VAF 73/258 reads (28%) | catalogued as COSV62231318; called by muse, mutect2, varscan2
- ASB17 | c.570G>A p.S190= | Silent (SNP) | VAF 57/284 reads (20%) | catalogued as rs141282823, COSV99407932; called by muse, mutect2, varscan2
- BACH2 | c.363G>A p.L121= | Silent (SNP) | VAF 120/326 reads (37%) | called by muse, mutect2, varscan2
- C18orf25 | c.921A>C p.L307= | Silent (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- CASP2 | c.657C>A p.R219= | Silent (SNP) | VAF 128/342 reads (37%) | called by muse, mutect2, varscan2
- CENPH | c.543A>G p.K181= | Silent (SNP) | VAF 72/138 reads (52%) | called by muse, mutect2, varscan2
- CES3 | c.609A>T p.V203= | Silent (SNP) | VAF 45/77 reads (58%) | called by muse, mutect2, varscan2
- CIZ1 | c.231C>T p.A77= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as rs1396302541; called by muse, mutect2, varscan2
- CREB3L3 | c.198C>A p.S66= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs1438203537; called by muse, mutect2, varscan2
- CUX2 | c.1143C>A p.T381= | Silent (SNP) | VAF 58/150 reads (39%) | called by muse, mutect2, varscan2
- DHX36 | c.612A>G p.R204= | Silent (SNP) | VAF 97/306 reads (32%) | called by muse, mutect2, varscan2
- DNASE1L2 | c.150G>T p.L50= | Silent (SNP) | VAF 28/101 reads (28%) | called by muse, mutect2, varscan2
- DOCK1 | c.2991G>C p.L997= | Silent (SNP) | VAF 68/164 reads (41%) | called by muse, mutect2, varscan2
- ECE1 | c.1686G>A p.P562= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs1015101788; ClinVar: likely benign; called by muse, mutect2, varscan2
- EMILIN1 | c.747C>T p.T249= | Silent (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
- FADS6 | c.729C>T p.F243= | Silent (SNP) | VAF 68/171 reads (40%) | catalogued as rs748560757, COSV59601985; called by muse, mutect2, varscan2
- FAM135B | c.522T>A p.A174= | Silent (SNP) | VAF 31/101 reads (31%) | called by muse, mutect2, varscan2
- GFRA2 | c.1296G>T p.G432= | Silent (SNP) | VAF 83/156 reads (53%) | called by muse, mutect2, varscan2
- GSG1L | c.612C>A p.L204= (on ENST00000447459 / NM_001109763.2; = p.L49= on NM_144675.2) | Silent (SNP) | VAF 50/118 reads (42%) | catalogued as COSV66576791, COSV66579869; called by muse, mutect2, varscan2
- IGF2BP1 | c.1725G>T p.R575= | Silent (SNP) | VAF 69/192 reads (36%) | catalogued as COSV51730230; called by muse, mutect2, varscan2
- JCHAIN | c.408C>G p.V136= | Silent (SNP) | VAF 12/338 reads (4%) | catalogued as COSV99636234; called by muse, mutect2
- KCNJ11 | c.66C>T p.A22= | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as rs768189518; called by muse, mutect2
- LCN9 | c.354G>A p.L118= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as rs752155644; called by muse, mutect2, varscan2
- MAP2 | c.4779C>T p.P1593= | Silent (SNP) | VAF 61/102 reads (60%) | called by muse, mutect2, varscan2
- MFAP5 | c.360C>T p.N120= | Silent (SNP) | VAF 80/282 reads (28%) | called by muse, mutect2, varscan2
- MLXIPL | c.93C>T p.D31= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs1554603113, COSV57667716; called by muse, mutect2, varscan2
- MUC16 | c.33729G>T p.G11243= | Silent (SNP) | VAF 25/188 reads (13%) | called by muse, mutect2, varscan2
- NLRP2 | c.426C>T p.I142= | Silent (SNP) | VAF 57/390 reads (15%) | called by muse, mutect2, varscan2
- NRXN1 | c.102G>A p.P34= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1381510304; called by muse, varscan2
- OR2T2 | c.852C>T p.P284= | Silent (SNP) | VAF 66/459 reads (14%) | called by muse, varscan2
- OR52K1 | c.405G>C p.T135= | Silent (SNP) | VAF 41/258 reads (16%) | catalogued as rs767653676, COSV56903469; called by muse, mutect2, varscan2
- OR52N1 | c.126A>T p.T42= | Silent (SNP) | VAF 76/233 reads (33%) | catalogued as COSV57693995; called by muse, mutect2, varscan2
- OR5D18 | c.36G>C p.T12= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- OSGIN2 | c.939C>A p.A313= | Silent (SNP) | VAF 111/279 reads (40%) | called by muse, mutect2, varscan2
- PARVB | c.603G>A p.E201= | Silent (SNP) | VAF 39/184 reads (21%) | called by muse, mutect2, varscan2
- PCNT | c.5343G>T p.G1781= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV100855783; called by muse, mutect2, varscan2
- PPM1E | c.1494T>C p.S498= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV57574986; called by muse, mutect2, varscan2
- SALL3 | c.1110C>G p.G370= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV73305815; called by muse, mutect2, varscan2
- SCN4A | c.1917G>A p.Q639= | Silent (SNP) | VAF 32/187 reads (17%) | called by muse, mutect2, varscan2
- SLC15A3 | c.642G>T p.L214= | Silent (SNP) | VAF 45/168 reads (27%) | called by muse, mutect2, varscan2
- SLC1A2 | c.576G>T p.T192= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV53521949; called by muse, mutect2, varscan2
- SNPH | c.1389C>G p.G463= | Silent (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- SPATA31D1 | c.4275C>A p.I1425= | Silent (SNP) | VAF 55/150 reads (37%) | called by muse, mutect2, varscan2
- SUGCT | c.948A>G p.V316= | Silent (SNP) | VAF 52/277 reads (19%) | called by muse, mutect2, varscan2
- SVOP | c.1594C>A p.R532= | Silent (SNP) | VAF 148/336 reads (44%) | catalogued as rs751699856; called by muse, varscan2
- TAC4 | c.231C>A p.I77= | Silent (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- TCAF2 | c.808C>T p.L270= | Silent (SNP) | VAF 11/21 reads (52%) | called by mutect2, varscan2
- TFAP2D | c.745T>C p.L249= | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as rs549396552; called by muse, mutect2, varscan2
- TLE2 | c.732C>T p.P244= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, varscan2
- TMEM126B | c.27G>T p.G9= | Silent (SNP) | VAF 66/296 reads (22%) | called by muse, mutect2, varscan2
- TMEM132A | c.759C>T p.D253= | Silent (SNP) | VAF 41/174 reads (24%) | catalogued as rs144698752; called by muse, mutect2, varscan2
- TMEM209 | c.111A>G p.V37= | Silent (SNP) | VAF 80/235 reads (34%) | called by muse, mutect2, varscan2
- TRBV30 | c.258C>T p.P86= | Silent (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- TRPM6 | c.855C>G p.G285= | Silent (SNP) | VAF 95/476 reads (20%) | catalogued as COSV62507849; called by muse, mutect2, varscan2
- TUBG2 | c.648C>T p.D216= | Silent (SNP) | VAF 59/304 reads (19%) | catalogued as rs536564774; called by muse, mutect2, varscan2
- TXNRD1 | c.360G>T p.L120= (on ENST00000525566 / NM_001093771.3; = p.L22= on NM_003330.4) | Silent (SNP) | VAF 42/123 reads (34%) | called by muse, mutect2, varscan2
- UGGT1 | c.3369A>T p.T1123= | Silent (SNP) | VAF 55/301 reads (18%) | called by muse, mutect2, varscan2
- WDR97 | c.4170C>T p.F1390= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs565423478; called by muse, mutect2, varscan2
- ZNF358 | c.1188G>T p.V396= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs752017987; called by muse, mutect2, varscan2
- ZNF385A | c.558G>A p.L186= (on ENST00000338010 / NM_001130967.3; = p.L166= on NM_015481.3) | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as rs377099940; called by muse, mutect2, varscan2
- ZNF84 | c.2028A>C p.T676= | Silent (SNP) | VAF 48/207 reads (23%) | called by muse, mutect2, varscan2
- AC004890.2 | n.2204G>T | RNA (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40448177 A>T | 5'Flank (SNP) | VAF 13/59 reads (22%) | catalogued as rs1482518931; called by muse, mutect2
- AC244517.10 | c.36-8972T>A | Intron (SNP) | VAF 95/205 reads (46%) | catalogued as rs782396067, COSV73145046; called by muse, mutect2, varscan2
- ACP2 | c.114+127A>T | Intron (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
- ADAM3A | n.1859C>G | RNA (SNP) | VAF 72/338 reads (21%) | called by muse, mutect2, varscan2
- ANO5 | c.*34T>C | 3'UTR (SNP) | VAF 105/276 reads (38%) | called by muse, mutect2, varscan2
- APOD | c.334+22G>T | Intron (SNP) | VAF 89/259 reads (34%) | called by muse, mutect2, varscan2
- ARL6IP6 | c.401-617T>G | Intron (SNP) | VAF 37/232 reads (16%) | called by muse, mutect2, varscan2
- C16orf89 | c.*28G>A | 3'UTR (SNP) | VAF 23/202 reads (11%) | catalogued as COSV100280762; called by muse, mutect2, varscan2
- C19orf12 | chr19:29700440 C>A | 3'Flank (SNP) | VAF 83/550 reads (15%) | called by muse, mutect2, varscan2
- C3orf18 | c.235-693T>A | Intron (SNP) | VAF 64/104 reads (62%) | called by muse, mutect2, varscan2
- COL3A1 | c.2661+30A>G | Intron (SNP) | VAF 102/240 reads (43%) | called by muse, mutect2, varscan2
- CTAGE11P | n.94T>C | RNA (SNP) | VAF 167/416 reads (40%) | catalogued as rs1207952233; called by muse, mutect2, varscan2
- ELOVL5 | c.58+1351C>T | Intron (SNP) | VAF 18/62 reads (29%) | catalogued as rs1277856549, COSV58652125; called by muse, mutect2, varscan2
- FAM182B | n.490G>T | RNA (SNP) | VAF 89/490 reads (18%) | called by muse, mutect2, varscan2
- FBXL17 | c.1965+51T>C | Intron (SNP) | VAF 70/161 reads (43%) | called by muse, mutect2, varscan2
- FMNL1 | c.328-140G>T | Intron (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- FOLH1B | n.956G>T | RNA (SNP) | VAF 70/245 reads (29%) | called by muse, mutect2, varscan2
- GDF6 | c.*14G>A | 3'UTR (SNP) | VAF 74/182 reads (41%) | catalogued as rs1006798221; called by muse, mutect2, varscan2
- GRM5 | c.661+62420C>G | Intron (SNP) | VAF 64/167 reads (38%) | called by muse, mutect2, varscan2
- IFT27 | c.35-148G>T | Intron (SNP) | VAF 34/194 reads (18%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.1235+997C>T | Intron (SNP) | VAF 73/179 reads (41%) | catalogued as rs769932725; called by muse, mutect2, varscan2
- IGKV1-13 | n.146C>G | RNA (SNP) | VAF 187/579 reads (32%) | called by muse, varscan2
- KBTBD3 | c.233+25G>T | Intron (SNP) | VAF 102/199 reads (51%) | catalogued as rs372797089; called by muse, mutect2, varscan2
- KDM4C | c.2610+1541C>A | Intron (SNP) | VAF 37/67 reads (55%) | catalogued as rs1383666969; called by muse, mutect2, varscan2
- MALAT1 | n.27C>A | RNA (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- NDUFAF4 | c.-33G>A | 5'UTR (SNP) | VAF 124/420 reads (30%) | called by muse, mutect2, varscan2
- NOD2 | c.3050+28G>C | Intron (SNP) | VAF 70/203 reads (34%) | called by muse, mutect2, varscan2
- NPIPB10P | n.258C>T | RNA (SNP) | VAF 121/481 reads (25%) | called by muse, mutect2, varscan2
- NUDCD3 | c.509+16828T>C | Intron (SNP) | VAF 64/493 reads (13%) | catalogued as rs764181826, COSV62647494; called by muse, varscan2
- PCDH11X | c.3144+24859C>A | Intron (SNP) | VAF 40/83 reads (48%) | catalogued as COSV53501592; called by muse, mutect2, varscan2
- PLEKHA5 | c.1846-14154G>A | Intron (SNP) | VAF 30/99 reads (30%) | catalogued as rs1263666732; called by muse, mutect2, varscan2
- PPP1R2 | c.230+1926A>T | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as rs896686216; called by muse, mutect2
- PPP1R9A | c.1890+5232A>T | Intron (SNP) | VAF 23/159 reads (14%) | called by muse, varscan2
- PRR27 | c.51+325T>A | Intron (SNP) | VAF 115/220 reads (52%) | called by muse, mutect2, varscan2
- PTPN6 | chr12:6946686 C>T | 5'Flank (SNP) | VAF 66/168 reads (39%) | catalogued as rs1357778124, COSV57546935; called by muse, mutect2, varscan2
- PYGO1 | c.49+936G>T | Intron (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- SEL1L2 | c.387-1234C>T | Intron (SNP) | VAF 87/360 reads (24%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.872G>A | RNA (SNP) | VAF 9/29 reads (31%) | catalogued as rs921948142; called by muse, mutect2, varscan2
- SYNGR3 | c.338-14C>T | Intron (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- SZRD1 | c.*67C>T | 3'UTR (SNP) | VAF 59/158 reads (37%) | called by muse, mutect2, varscan2
- TBCD | c.1983+476C>T | Intron (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- TLR4 | c.*37C>A | 3'UTR (SNP) | VAF 100/264 reads (38%) | called by muse, mutect2, varscan2
- TSBP1 | chr6:32288619 T>G | 3'Flank (SNP) | VAF 65/252 reads (26%) | called by muse, mutect2, varscan2
- UNC5D | c.*2622C>T | 3'UTR (SNP) | VAF 54/162 reads (33%) | catalogued as rs1362440139; called by muse, mutect2, varscan2
- XK | c.*46G>A | 3'UTR (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- XKR6 | c.764+62815C>G | Intron (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2
- ZNF252P | chr8:145003073 G>A | 5'Flank (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- ZNF849P | n.916G>T | RNA (SNP) | VAF 68/259 reads (26%) | called by muse, varscan2
- ZNF971P | n.288G>A | RNA (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
